Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A03X, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A03X-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: Infiltrative ductal carcinoma

Date of Procurement: Anatomic Site: **Left Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **Frozen**

Container: **cryomold** Type of Procurement: **Radical mastectomy** Grade: **1**

T Stage: **2** N Stage: **0** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement

1CD-0-3

carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9
lw
10/21/11

Source: NCI Genomic Data Commons file ace98e97-6839-4874-93b0-0dd4de04af38 (TCGA-AN-A03X.1F6200B4-B53B-4E9F-B01B-12D2C0D4270E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).